CCDI case PBCTEJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/dfe65906-b6b0-4f98-aae1-afc7e8e0f0ae

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Other ill-defined sites; Age at diagnosis: 15.1 years (5,507 days).

Biospecimens (3 samples)
- Sample 0DZEGL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DZEGX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZEHL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
